Somatic mutation profile of tumor specimen TCGA-KK-A8II-01A (aliquot TCGA-KK-A8II-01A-11D-A364-08) from TCGA case TCGA-KK-A8II, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.5 years (22,460 days).
Specimen TCGA-KK-A8II-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25a73c6c-e955-411e-b0e0-22b2c0a53127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8II-11A (Solid Tissue Normal), aliquot TCGA-KK-A8II-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3785ad61-2ee8-40c5-b2ea-6d9bd6c3aa78

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 19, Silent 11, Nonsense Mutation 4, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-2_376-1del p.X126_splice | Splice Site (DEL) | VAF 5/10 reads (50%) | hotspot (GDC flag); called by mutect2, varscan2
- ATP1B2 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs200828135; called by muse, mutect2
- CD34 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146542924; called by muse, mutect2, varscan2
- CDH9 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV99151124; called by muse, mutect2
- CYP4B1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs45578838; called by muse, mutect2, varscan2
- EMILIN3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100182754; called by muse, mutect2, varscan2
- FANK1 | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100904810; called by muse, mutect2
- GLUD2 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100047025; called by muse, mutect2, varscan2
- GOLGA4 | c.3745A>G p.R1249G | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV100729084; called by muse, mutect2, varscan2
- ITSN1 | c.2798A>C p.N933T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV101180609; called by muse, mutect2
- KLHL20 | c.739C>A p.R247S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV52941857, COSV99268601; called by muse, mutect2, varscan2
- KMT2C | c.7160T>G p.L2387* | Nonsense Mutation (SNP) | VAF 58/133 reads (44%) | catalogued as COSV100075120; called by muse, mutect2, varscan2
- MCCC1 | c.1359C>A p.Y453* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV99659982; called by muse, mutect2, varscan2
- ONECUT1 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1483480013, COSV100009372; called by muse, mutect2, varscan2
- OR4C3 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1261968772, COSV60587224; called by muse, mutect2, varscan2
- POM121 | c.1493C>T p.P498L (on ENST00000434423; = p.P233L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV99988983; called by muse, mutect2, varscan2
- RPL3L | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs149043671; called by muse, mutect2, varscan2
- TCTN1 | c.*1C>T | Splice Region (SNP) | VAF 17/38 reads (45%) | catalogued as rs766525586, COSV99657364; called by muse, mutect2, varscan2
- TEX26 | c.445A>T p.R149* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV100994118; called by muse, mutect2, varscan2
- TFG | c.299G>C p.S100T | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV99561171; called by muse, mutect2, varscan2
- TMEM178A | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as rs1277564244, COSV99932003; called by muse, mutect2, varscan2
- TMPRSS11D | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs370881465; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 32/60 reads (53%) | catalogued as rs1245733568, COSV100389832; called by muse, mutect2, varscan2
- TTC39B | c.1602C>G p.I534M | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as COSV99895879; called by muse, mutect2
- YARS2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs750572052, COSV100256511; called by muse, mutect2, varscan2
- EPAS1 | c.1732del p.A578Pfs*118 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- FAM111A | c.1439dup p.Q481Afs*3 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | called by mutect2, varscan2
- ACSBG1 | c.55C>T p.L19= | Silent (SNP) | VAF 86/200 reads (43%) | catalogued as COSV99357693; called by muse, mutect2, varscan2
- ACTL7B | c.492G>A p.A164= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs114146670, COSV65928128; called by muse, mutect2, varscan2
- ASTN2 | c.1140G>C p.G380= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100529457, COSV57754786; called by muse, mutect2, varscan2
- DDX56 | c.822A>G p.L274= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99346201; called by muse, mutect2, varscan2
- EYS | c.885A>C p.A295= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as COSV100676988; called by muse, mutect2, varscan2
- HECW1 | c.1884G>A p.A628= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1348906997, COSV67830662; called by muse, mutect2, varscan2
- ISM2 | c.729C>T p.P243= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs771705815, COSV99376819; called by muse, mutect2, varscan2
- PCDHA2 | c.1329C>T p.I443= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs901353156, COSV65368307; called by muse, mutect2, varscan2
- PIK3CD | c.2682G>A p.R894= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV63126819; called by muse, mutect2
- RAB4A | c.285C>T p.I95= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100797070; called by muse, mutect2, varscan2
- TEX13A | c.382C>A p.R128= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV61162800; called by muse, mutect2
